Surgical pathology report (de-identified scan), TCGA case TCGA-S6-A8JW, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Gundersen Lutheran Health System, specimen TCGA-S6-A8JW-01A (Primary Tumor).

[page 1 of 3]
Patient:

Med. Record. No.: [REDACTED]

Date of Birth: [REDACTED]

Submitted by: [REDACTED]

Report also to: [REDACTED]

Age: [REDACTED]

Sex: M

Pathology #: [REDACTED]

Date of Procedure: [REDACTED]

Date Received: [REDACTED]

Pathology Report

DIAGNOSIS:

ICD-O-3
Seminoma NOS 9061/3
Site: (R) Testis NOS C62.9
Op 1/29/14

SPECIMEN

Specimen type: Left radical orchiectomy

TUMOR

Histologic type: Seminoma

Tumor size (greatest dimension): 5.4cm

Tumor focality: Unifocal within testis

Involvement of rete testis: Absent

Venous/lymphatic invasion: Absent

Extent of direct tumor invasion: No direct tumor extension beyond testis

Additional findings: Intratubular germ cell neoplasia

MARGINS

All margins negative for tumor

LYMPH NODES

Cannot be assessed

SERUM TUMOR MARKERS

S0: Serum marker studies within normal limits

STAGING (AJCC)

Primary Tumor: pT1

Lymph Nodes: pNX

Distant Metastasis: Cannot be assessed

ADDITIONAL COMMENTS

Comment:

IHC results support the diagnosis of pure seminoma. See IHC table below.

This case, including the IHC results, is reviewed with [REDACTED] who concurs with the diagnosis of pure seminoma.

[page 2 of 3]
Patient: [REDACTED]

MRN: [REDACTED]

CLINICAL INFORMATION:

Mass left testicle

SPECIMEN(S) RECEIVED:

Left testicle - 1

GROSS DESCRIPTION:

Received fresh is a 90-gram left radical orchiectomy with 7.0 x 4.8 x 3.8 cm testis, 6.5 x 1.2 x 0.7 cm epididymis and 14.0 x 2.5 x 1.5 cm spermatic cord. Sectioning through the tunica vaginalis reveals a small amount of thin, serous fluid. The tunica albuginea is smooth and pale blue-gray. The epididymis is unremarkable without masses or cysts. Within the testis is a diffusely solid, well-circumscribed 5.4 x 4.5 x 3.2 cm mottled red-tan to red-purple mass. The mass extends to but does not penetrate through the tunica albuginea. There is no gross involvement of the epididymis or the spermatic cord. The adjacent testicular parenchyma is spongy and tan. No additional lesions are identified. Both samples of the mass as well as normal parenchyma are obtained for the

Photographs are taken. Sections submitted: A1-A3 - tumor to include adjacent normal testis; A4 - normal testis and epididymis; A5 - proximal spermatic cord; A6 - mid spermatic cord; A7 - distal cord margin.

Immunohistochemistry Results

Formalin-fixed, paraffin-embedded tissue is utilized. Tissue sections are incubated with the following antibodies. Controls stain appropriately. Complete procedural methodology is available upon request. Results indicated below:

Material: Block A1

Marker For:	Result	Comment
CD30	Negative	
Alpha-fetoprotein (AFP)	Negative	
Human chorionic gonadotropin (HCG)	Negative	

Material: Block A2

Marker For:	Result	Comment
CD30	Negative	
Alpha-fetoprotein (AFP)	Negative	
Human chorionic gonadotropin (HCG)	Negative	

Material: Block A3

Marker For:	Result	Comment
CD30	Negative	
Alpha-fetoprotein (AFP)	Negative	
Human chorionic gonadotropin (HCG)	Negative	

Note: The performance characteristics of all immunohistochemical stains cited in this report were determined by the Department of Pathology at [REDACTED] as part of an ongoing quality assurance program and in compliance with federally mandated regulations drawn from the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88). Some of these tests may rely on the use of "analyte specific reagents" and have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or

[page 3 of 3]
Patient: [REDACTED]

MRN: [REDACTED]

approval is not necessary. Nevertheless, federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to this report. These tests are used for clinical purposes, and should not be regarded as investigational or for research. The immunohistochemistry laboratory at [REDACTED] is certified by the Centers for Medicare and Medicaid Services (formerly HCFA) as a high complexity laboratory under CLIA '88.

Slides were microscopically examined by the pathologist.

Evaluation performed by [REDACTED]

Electronically signed

HI/PA Discrepancy		

Pathology Report

Page 3 of 3

Source: NCI Genomic Data Commons file aade3bb2-3a5d-4976-b97d-88bc43e06fa4 (TCGA-S6-A8JW.EC2022F6-2FB7-4D53-8176-C8584C3CE2CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).